Gene-level copy-number profile of tumor specimen TCGA-2G-AAHZ-01A from TCGA case TCGA-2G-AAHZ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 38.0 years (13,887 days).
Specimen TCGA-2G-AAHZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c2eb8166-cf72-4cb6-b416-076475831612.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/f9a5a52f-9aeb-47ea-8415-7a1e48a69877

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 515; copy number 1: 1,388; copy number 2: 29,911; copy number 3: 18,638; copy number 4: 6,482; copy number 5: 29; copy number 6: 1,243; copy number 7: 390; copy number 8: 96; copy number 9: 33; copy number 12: 160; copy number 13: 14.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–71,585, 3 genes: OR4G4P, OR4G11P, OR4F5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,965 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:188,713,644–189,661,486, 12 genes, copy number 5: AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262.
- chr8:64,091–37,331,991, 742 genes, copy number 6–7 (broad region; genes not listed).
- chr8:46,549,089–71,228,629, 366 genes, copy number 6–13 (within-gene range 4–13) (broad region; genes not listed).
- chr8:116,642,130–117,318,701, 13 genes, copy number 5: EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1.
- chr12:66,767–37,576,384, 832 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 978. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
